Surgical pathology report (de-identified scan), TCGA case TCGA-06-1805, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-1805-01A (Primary Tumor).

[page 1 of 3]
Genomic Pathology Report

TCGA-06-1805

CLINICAL HISTORY

GBM

OPERATIVE DIAGNOSES

Operation/Specimen: A: Brain, left frontal, biopsy
B: Brain, left temporal msas, excision biopsy

PATHOLOGICAL DIAGNOSIS:

Brain, left frontal lesion, excision: Glioblastoma (WHO Grade IV) (see comment).

COMMENT

Sections show a pleomorphic high-grade glioma demonstrating frequent mitotic figures, vascular proliferation and necrosis. The histology is most consistent with the small cell variant of glioblastoma.

The tumor shows strong diffuse p53 immunoreactivity and the Ki-67 labeling index is approximately 25%.

MGMT promoter methylation and EGFRvIII mutation assays are pending and will be reported below in procedure addenda.

PROCEDURES/ADDENDA

Addendum

Date Ordered: Date Reported:

Addendum Diagnosis

EGFRvIII Mutation Assay

NEGATIVE No evidence of EGFRvIII mutation is detected

Test Description

Testing performed on RNA extracted from tissue paraffin block

The epidermal growth factor receptor (EGFR) is an attractive molecular target

[page 2 of 3]
[REDACTED]

in glioblastoma because it is often amplified, overexpressed, and/or mutated in up to 40% to 50% of patients. EGFR variant III (EGFRvIII) is an oncogenic, constitutively active mutant form of EGFR resulting from deletion of exons 2/3 which is commonly expressed in glioblastoma. Cell culture and in vivo models of glioblastoma have demonstrated EGFRvIII as defining prognostically distinct subgroups of glioblastomas. Additionally, the presence of EGFRvIII has been shown to sensitize tumors to EGFR tyrosine kinase inhibitors when the tumor suppressor protein PTEN is intact.

RNA is extracted from formalin fixed, paraffin embedded tissue samples and reverse transcribed to cDNA. The cDNA is then amplified using standard PCR technique for DNA templates including the housekeeping genes for testing RNA integrity. PCR products are detected by gel electrophoresis. The limit of detection of this assay has been determined to be approximately 5 mutant cells in 100 normal cells.

FDA Comment: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

CPT Codes: 83907, 83890 (RNA isolation), 83902, 83898, 83894, 83912 [REDACTED]

TCGA-06-1805

[REDACTED]

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tissue paraffin block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

Senior Staff Pathologist

=====

INTRA-OPERATIVE CONSULTATION

Requested by: _____

[page 3 of 3]
[REDACTED]

A. Brain, left frontal lesion, biopsy: Glioblastoma. Frozen sections and smears performed at [REDACTED] and reported to the physician of record on [REDACTED]

[REDACTED] Senior Staff Pathologist [REDACTED]

TCGA-06-1805

GROSS DESCRIPTION

A. SPECIMEN: Brain, left frontal, biopsy:

FIXATIVE: Fresh

GENERAL: Multiple segments of gray white brain parenchyma with separate blood clot, 3.0x3.0x1.8 cm aggregate.

SECTIONS: A1- frozen section remnant, A2-A3 representative.

B.

SPECIMEN: Left frontal brain mass.

FIXATIVE: None.

GENERAL: Received is a 2.5 x 2 x 1.1 cm. irregular gray-white friable tissue fragment.

SECTIONS: Specimen is entirely submitted in two cassettes.

[REDACTED]

ICD-9(s):
191.1 191.1

[REDACTED]

Histo Data

Part A: Brain, left frontal, biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
FS H/E x 1	1	[REDACTED]	
H/E x 1	1	[REDACTED]	
TPS H/E x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	
H/E x 1	3	[REDACTED]	
MIB1-DA x 1	3	[REDACTED]	

Part B: Brain, left temporal msas, excision biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	
MGMT-curles x 1	2	[REDACTED]	
MIB1-DA x 1	2	[REDACTED]	
P53DO7 x 1	2	[REDACTED]	
EGFR-curles x 1	(none)	[REDACTED]	For EGFRvIII

*** End of Report ***

Source: NCI Genomic Data Commons file 22e97979-5df3-4cc5-ad86-20f7276d7500 (TCGA-06-1805.0DAB6572-812F-4FDC-9A25-495652A560E0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).